Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2X, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2X-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:
Soft tissue sarcoma vs melanoma.

Specimens Submitted:
1: SP: Right leg mass

DIAGNOSIS:

1. SP: RIGHT LEG MASS; RESECTION:
- HIGH GRADE UNDIFFERENTIATED SPINDLE, EPITHELIOID AND PLEOMORPHIC NEOPLASM MOST CONSISTENT WITH UNDIFFERENTIATED SARCOMA.
- TUMOR SIZE: 8 X 6 X 3 CM.
- NECROSIS PRESENT (20% GROSS ESTIMATE)
- VASCULAR INVASION IS PRESENT.
- SKIN WITH SURFACE SUPERFICIAL ULCER
- MARGINS ARE NEGATIVE. CLOSEST MARGIN IS DEEP-1MM FROM TUMOR LIMITED BY FASCIA.

NOTE: IMMUNOHISTOCHEMICAL STAINS SHOW THAT THE TUMOR CELLS ARE NEGATIVE FOR MELANOMA MARKERS (S-100, HMB-45, TYROSINASE, A-103), CYTOKERATIN AE1/AE3, p63/4A4, DESMIN, LCA, CD30, ALK-1, AND CD34. RARE POSITIVITY IS SEEN WITH CD31 AND FOCAL LABELLING IS SEEN WITH CD163. THESE FINDINGS IN ADDITION TO THE IMMUNOS PERFORMED ON PREVIOUS BIOPSY (POSITIVITY FOR VIMENTIN, FOCAL SMA, FOCAL CD31 AND NEGATIVE STAINING FOR EMA, CD34, DESMIN, MYOGENIN, CAM 5.2, FLI-1, CD68 AND P63) DO NOT SUPPORT ANY SPECIFIC LINEAGE. BASED ON NEGATIVE STAINING FOR MELANOMA MARKERS, CYTOKERATINS AND LCA, THIS TUMOR IS BEST CLASSIFIED AS AN UNDIFFERENTIATED PLEOMORPHIC SARCOMA.

Note:

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

** Continued on next page **

TC0-0.3

Sarcoma, pleomorphic, undifferentiated
(8802/3) *(8805/3)*
Code to high 8805/3
Site 1 - Leg NOS 049.2
3/10/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh labeled "right leg mass" and consists of an oriented by sutures rhombus-shaped large skin excision measuring 16 x 12 x 4.5 cm with a slightly eccentric hemorrhagic ulcer measuring 1 x 0.5 cm. The margins are inked as follows: deep = black, lateral = blue and medial = green. Serial sectioning reveals a non-encapsulated lobulated grey fleshy solid tissue mass measuring 8 x 6 x 3 cm. Approximately 20% of the mass shows grossly appreciable tumor necrosis. The specimen is photographed and sampled for TPS. Representative sections are submitted.

Summary of sections:

T tumor mass
S normal skin
U ulcer
SM superior margin
IM inferior margin
MM medial margin
LM lateral margin
DP deep margin

Summary of Sections:
Part 1: SP: Right leg mass

Block	Sect.	Site	PCs
1		dm	1
1		im	1
1		lm	1
1		mm	1
1		s	1
1		sm	1
8		t	8
1		u	1

** End of Report **

Source: NCI Genomic Data Commons file 474f4954-7393-4434-9460-52585dcafbdc (TCGA-DX-AB2X.6A1D8D3D-73BB-4277-AAAC-CBE5F6AFB664.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).